Somatic mutation profile of tumor specimen MMRF_1999_1_BM_CD138pos (aliquot MMRF_1999_1_BM_CD138pos_T1_KHS5U_L08067) from MMRF case MMRF_1999, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.4 years (19,504 days).
Specimen MMRF_1999_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14b9f9a5-5193-4e2e-8453-3d278c7a022b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1999_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1999_1_PB_Whole_C2_KHS5U_L08068; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b73933af-2216-4113-a2f5-5ffc5089e28a

The open-access MAF lists 232 somatic variants for this specimen: 89 protein-altering or splice-affecting, 30 silent, 113 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, 3'UTR 53, Intron 38, Silent 30, 5'Flank 10, 5'UTR 6, 3'Flank 3, RNA 3, Splice Site 3, Splice Region 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.2832+1G>A p.X944_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as rs1135401809, COSV65037460, COSV65040731; ClinVar: pathogenic; called by muse, mutect2
- ACAN | c.4883G>T p.G1628V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61363243; called by muse, mutect2, varscan2
- ANKRD11 | c.4617G>C p.E1539D | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99967914; called by muse, mutect2
- ANKRD11 | c.4285G>C p.D1429H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1477477198, COSV56374783; called by muse, mutect2
- ARHGAP42 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs939412084; called by muse, mutect2, varscan2
- ATP5F1D | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1304586305; called by muse, mutect2
- BRF1 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.267); catalogued as rs1263125046, COSV59266610; called by muse, mutect2, varscan2
- C11orf54 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as rs758601498; called by muse, mutect2, varscan2
- CCDC168 | c.7865A>G p.E2622G | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV70555072; called by muse, mutect2, varscan2
- CHD3 | c.4738del p.E1580Rfs*38 | Frame Shift Del (DEL) | VAF 40/141 reads (28%) | catalogued as COSV57878198; called by mutect2, pindel, varscan2
- DNAH11 | c.8371G>A p.D2791N | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs752427757; called by muse, mutect2, varscan2
- DOCK1 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757225154; called by muse, mutect2, varscan2
- EIF3K | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs759935141; called by muse, mutect2, varscan2
- ERBB2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775382058; called by muse, mutect2, varscan2
- FAM83H | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs782016000; called by muse, mutect2
- FCHO1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs148410831; called by muse, mutect2, varscan2
- FFAR3 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs573119901; called by muse, mutect2, varscan2
- FLG2 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 143/240 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1441003224; called by muse, mutect2, varscan2
- GKN1 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs776814123; called by muse, mutect2, varscan2
- IGHV2-70 | c.253A>C p.K85Q | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs755889609; called by muse, mutect2, varscan2
- IGLV3-1 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 48/48 reads (100%) | catalogued as rs181922188; called by muse, mutect2, varscan2
- IGLV3-21 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs540297754; called by muse, varscan2
- IGLV3-21 | c.333T>G p.S111R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs375582212; called by muse, varscan2
- KLHL14 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63834726; called by muse, mutect2, varscan2
- LARP4B | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337319874, COSV60220607, COSV60221275; called by muse, mutect2, varscan2
- LCLAT1 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV100474627; called by muse, mutect2, varscan2
- MANEA | c.730A>C p.K244Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs1171273969; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54315364; called by muse, mutect2, varscan2
- MINDY4B | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.087); catalogued as rs950159673; called by muse, mutect2
- MRC1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs782098996, COSV100509732; called by muse, mutect2, varscan2
- NAP1L3 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV59073823; called by muse, mutect2, varscan2
- NLRP13 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV61624559; called by muse, mutect2
- NRG1 | c.754G>A p.A252T (on ENST00000405005 / NM_013964.5; = p.A257T on NM_013956.5) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs771092162, COSV55152234, COSV99827524; called by muse, mutect2, varscan2
- PABPC1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59401924; called by muse, mutect2, varscan2
- PDS5B | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141013786, COSV100221307; called by muse, mutect2, varscan2
- PSG1 | c.1144C>A p.R382S | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV54948843; called by muse, mutect2, varscan2
- RARA | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV99564946; called by muse, mutect2, varscan2
- RTN1 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774510449, COSV50724648; called by muse, mutect2, varscan2
- SH3RF3 | c.2644T>G p.F882V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV58680644; called by muse, mutect2, varscan2
- STRN | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs777542661; called by mutect2, varscan2
- SYMPK | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs367969885; called by muse, mutect2
- SYNE1 | c.6050+1G>T p.X2017_splice (on ENST00000367255 / NM_182961.4; = p.X2024_splice on NM_033071.3) | Splice Site (SNP) | VAF 14/159 reads (9%) | catalogued as rs1261272739; called by muse, mutect2
- TPI1 | c.112A>G p.M38V (on ENST00000229270; = p.M1? on NM_000365.6) | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs201432576, COSV57540147; called by muse, mutect2, varscan2
- TRAF2 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs200834553, COSV56038604; called by muse, mutect2, varscan2
- TRIP6 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51937930; called by muse, mutect2, varscan2
- TTN | c.11508G>T p.Q3836H (on ENST00000591111; = p.Q3790H on NM_003319.4) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV60104805; called by muse, mutect2, varscan2
- USP5 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs781856774; called by muse, mutect2, varscan2
- ZNF493 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.082); catalogued as COSV62750174; called by muse, mutect2, varscan2
- ADAMTS16 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP9 | c.3190G>C p.E1064Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARHGEF26 | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C11orf54 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- CCDC7 | c.3087G>C p.K1029N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CDH3 | c.2014G>T p.V672L | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIART | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CNTLN | c.1219A>T p.N407Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2
- CSAG2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- DSG2 | c.2897G>A p.R966K | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ELF4 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- EML5 | c.5352-3C>A | Splice Region (SNP) | VAF 10/19 reads (53%) | called by muse, varscan2
- FBLN1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- FNIP1 | c.1382C>A p.T461N | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM1 | c.504C>A p.S168R | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FUT7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 186/641 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- G6PC | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, varscan2
- IRF2 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LOXHD1 | c.329T>A p.I110N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAF | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSL3 | c.356A>C p.E119A | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MTCH1 | c.907-3C>T | Splice Region (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- MUC16 | c.26063C>G p.S8688C | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- OLAH | c.670A>C p.T224P (on ENST00000378228 / NM_001039702.3; = p.T277P on NM_018324.3) | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCCA | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PLEKHO1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- REEP3 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RFFL | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SCYL3 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDK2 | c.4130C>A p.A1377D | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TACC2 | c.4558G>A p.G1520S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TCF3 | c.820A>G p.M274V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TOMM70 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAF3 | c.1335C>G p.F445L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF3 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF5 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM17 | c.945G>C p.Q315H | Missense Mutation (SNP) | VAF 76/112 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- USH2A | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- WNK3 | c.1087A>G p.S363G | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZBTB45 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ZFAND4 | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- AMOT | c.1953C>T p.N651= (on ENST00000371959 / NM_001113490.1; = p.N242= on NM_133265.3) | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs372193689; called by muse, mutect2, varscan2
- ARHGEF10L | c.3810C>T p.L1270= | Silent (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- AUTS2 | c.3630G>A p.K1210= | Silent (SNP) | VAF 13/338 reads (4%) | called by muse, mutect2
- BMPR1B | c.48C>T p.L16= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- CLDN1 | c.12G>A p.A4= | Silent (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- CLK3 | c.1272G>A p.E424= (on ENST00000395066 / NM_001130028.1; = p.E276= on NM_003992.4) | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as rs779364907; called by muse, mutect2, varscan2
- COL6A6 | c.6243A>G p.R2081= | Silent (SNP) | VAF 44/191 reads (23%) | called by muse, mutect2, varscan2
- EEF2 | c.576C>T p.Y192= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs763451947; called by muse, mutect2, varscan2
- EIF3C | c.840G>A p.K280= | Silent (SNP) | VAF 115/508 reads (23%) | catalogued as rs919556193; called by muse, mutect2, varscan2
- EIF3CL | c.840G>A p.K280= | Silent (SNP) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- FNDC3A | c.2349G>A p.L783= (on ENST00000492622 / NM_001079673.2; = p.L727= on NM_014923.5) | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- HTR2A | c.1170C>A p.A390= | Silent (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- IP6K2 | c.210A>C p.V70= | Silent (SNP) | VAF 129/329 reads (39%) | called by muse, mutect2, varscan2
- LRRC1 | c.1560G>A p.V520= | Silent (SNP) | VAF 23/450 reads (5%) | called by muse, mutect2
- LRRC8E | c.783G>A p.L261= | Silent (SNP) | VAF 97/265 reads (37%) | called by muse, mutect2, varscan2
- MFSD6L | c.660G>A p.G220= | Silent (SNP) | VAF 44/131 reads (34%) | called by muse, mutect2, varscan2
- MYO1H | c.354C>T p.L118= | Silent (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- NCOA3 | c.54C>A p.R18= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- NGFR | c.942G>T p.L314= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99412970; called by muse, mutect2, varscan2
- PAPOLA | c.1878T>C p.P626= | Silent (SNP) | VAF 112/236 reads (47%) | called by muse, mutect2, varscan2
- PRDM2 | c.594C>G p.T198= | Silent (SNP) | VAF 83/210 reads (40%) | catalogued as rs773928052; called by muse, mutect2, varscan2
- RCC2 | c.159C>T p.D53= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs944615184; called by muse, mutect2, varscan2
- RPS4X | c.669C>T p.S223= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- SCN1B | c.609C>T p.I203= | Silent (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- SLC16A7 | c.1353G>A p.L451= | Silent (SNP) | VAF 57/241 reads (24%) | catalogued as COSV99676208; called by muse, mutect2
- SLC22A14 | c.1254C>T p.I418= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs368019294, COSV56198720; called by muse, mutect2, varscan2
- TAX1BP1 | c.2196C>T p.L732= | Silent (SNP) | VAF 91/266 reads (34%) | catalogued as rs367746678; called by muse, mutect2, varscan2
- TULP2 | c.1167T>C p.A389= | Silent (SNP) | VAF 60/286 reads (21%) | called by muse, mutect2, varscan2
- TXN | c.6G>A p.V2= | Silent (SNP) | VAF 79/236 reads (33%) | called by muse, mutect2, varscan2
- VWA8 | c.5262G>A p.E1754= | Silent (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- ABLIM2 | c.1516+223C>T | Intron (SNP) | VAF 61/114 reads (54%) | catalogued as rs757902740; called by muse, mutect2, varscan2
- AC114741.1 | n.124G>A | RNA (SNP) | VAF 51/111 reads (46%) | catalogued as rs762418907; called by muse, mutect2, varscan2
- ACAD8 | c.1195+774C>T | Intron (SNP) | VAF 4/57 reads (7%) | catalogued as rs1050748988; called by muse, mutect2
- AEBP2 | c.*1026A>C | 3'UTR (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- BEND4 | c.*1369G>A | 3'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- BMP8A | c.*161C>T | 3'UTR (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- BNC2 | chr9:16870690 C>T | 5'Flank (SNP) | VAF 61/190 reads (32%) | catalogued as rs781299095; called by muse, mutect2, varscan2
- C12orf73 | c.-10-64C>T | Intron (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- CACNB4 | c.63+213C>G | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- CCDC57 | c.2564-10241C>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- CCK | c.214+53G>T | Intron (SNP) | VAF 73/227 reads (32%) | called by muse, mutect2, varscan2
- CCM2 | c.31-10510C>T | Intron (SNP) | VAF 167/496 reads (34%) | catalogued as rs1472147878; called by muse, mutect2, varscan2
- CD8B2 | c.620+2784G>A | Intron (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- CDH19 | c.*1233del | 3'UTR (DEL) | VAF 25/55 reads (45%) | called by mutect2, pindel, varscan2
- CFAP20DC | chr3:59050082 C>T | 5'Flank (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- COLCA2 | chr11:111293861 C>G | 5'Flank (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- CPEB3 | c.*308C>G | 3'UTR (SNP) | VAF 16/65 reads (25%) | catalogued as rs1434395307; called by muse, mutect2, varscan2
- CRB2 | c.*1355C>T | 3'UTR (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- DDX10 | c.2450+22G>A | Intron (SNP) | VAF 24/100 reads (24%) | catalogued as rs759697223; called by muse, mutect2, varscan2
- DDX5 | c.441+21G>C | Intron (SNP) | VAF 115/354 reads (32%) | catalogued as rs782531960; called by muse, mutect2, varscan2
- DIAPH2 | c.3241+39985G>A | Intron (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- DIO2 | c.*3048del | 3'UTR (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- E2F1 | c.*1152C>T | 3'UTR (SNP) | VAF 3/26 reads (12%) | catalogued as rs1018177970; called by muse, mutect2
- E2F7 | c.*1701G>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- ELAVL4 | chr1:50106331 G>A | 5'Flank (SNP) | VAF 98/224 reads (44%) | catalogued as rs767243659, COSV63918317; called by muse, mutect2, varscan2
- EXOC6B | c.*3160A>C | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, varscan2
- EXOC6B | c.*3093A>T | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, varscan2
- FAT3 | c.*2725G>A | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- FKBP3 | c.-275T>A | 5'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- FNDC3B | c.*729A>G | 3'UTR (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- FOXO3B | chr17:18663200 G>C | 3'Flank (SNP) | VAF 18/271 reads (7%) | catalogued as rs558754494; called by muse, mutect2
- FRMPD4 | c.*2195C>T | 3'UTR (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- GABARAP | c.*400G>A | 3'UTR (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- GART | chr21:33542830 G>C | 5'Flank (SNP) | VAF 51/195 reads (26%) | called by muse, mutect2, varscan2
- GBF1 | c.4646-43G>A | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- GLYATL3 | c.*89C>T | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- GNAQ | c.*689C>T | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- GNL1 | c.*1265C>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- GNRH1 | c.-73C>T | 5'UTR (SNP) | VAF 10/204 reads (5%) | catalogued as rs999827521; called by muse, mutect2
- H3-2 | c.*2-36C>T | Intron (SNP) | VAF 86/260 reads (33%) | catalogued as rs782228798; called by muse, mutect2, varscan2
- HBS1L | c.430+1820C>A | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2
- HEG1 | c.*4537C>T | 3'UTR (SNP) | VAF 50/143 reads (35%) | called by muse, mutect2, varscan2
- HOXA11 | c.*360G>A | 3'UTR (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- IKBKE | c.1836-320C>A | Intron (SNP) | VAF 94/146 reads (64%) | catalogued as rs782121021; called by muse, mutect2, varscan2
- KCNC2 | c.*302C>T | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*1813C>G | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- KLHL9 | c.*2709G>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- KRTAP5-8 | c.*411T>C | 3'UTR (SNP) | VAF 7/172 reads (4%) | catalogued as rs1032720393; called by muse, mutect2
- LMLN | c.*3445C>T | 3'UTR (SNP) | VAF 35/111 reads (32%) | catalogued as rs942075016; called by muse, mutect2, varscan2
- LTB | c.163-41G>A | Intron (SNP) | VAF 157/323 reads (49%) | catalogued as rs4647183, COSV53001370; called by muse, mutect2, varscan2
- LYRM7 | c.*2812G>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- MALRD1 | c.4688-118T>G | Intron (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- MBNL2 | c.*893T>A | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- METTL6 | c.*136G>C | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- MIB1 | c.*5274C>T | 3'UTR (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- MMP24 | c.*2245G>A | 3'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- MNX1 | c.691+467G>C | Intron (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- MOB1A | c.*1062G>A | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- MPPE1 | c.745-20C>T | Intron (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- MPPED1 | c.-79+6383C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- MS4A3 | c.*417G>C | 3'UTR (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- MYD88 | c.*283C>G | 3'UTR (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- MYOM3 | c.3424-341G>A | Intron (SNP) | VAF 90/175 reads (51%) | called by muse, mutect2, varscan2
- NEBL | c.*5250C>T | 3'UTR (SNP) | VAF 4/101 reads (4%) | called by muse, mutect2
- NISCH | c.1528+869G>A | Intron (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- NOP56 | c.208+57C>A | Intron (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- PCMT1 | c.*237G>A | 3'UTR (SNP) | VAF 8/108 reads (7%) | catalogued as rs1298983455; called by muse, mutect2
- PDE7A | c.-389C>G | 5'UTR (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- PIK3CA | c.*1258A>C | 3'UTR (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*6812C>G | 3'UTR (SNP) | VAF 19/73 reads (26%) | catalogued as rs955509331; called by muse, mutect2, varscan2
- PMPCB | c.*998G>C | 3'UTR (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- PNRC1 | c.-95C>T | 5'UTR (SNP) | VAF 37/281 reads (13%) | catalogued as rs1190711967; called by muse, mutect2, varscan2
- PRMT2 | c.*320A>G | 3'UTR (SNP) | VAF 6/158 reads (4%) | catalogued as rs1426755992; called by muse, mutect2
- PRR18 | c.*1410C>T | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- PRR23C | c.*1145G>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- PSMB8 | chr6:32844529 G>C | 5'Flank (SNP) | VAF 67/125 reads (54%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+4876A>C | Intron (SNP) | VAF 65/112 reads (58%) | called by muse, mutect2, varscan2
- PYCR1 | c.-204C>G | 5'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-654C>T | Intron (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- RC3H1 | c.*4553C>T | 3'UTR (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2, varscan2
- RIMS1 | chr6:72401710 G>C | 3'Flank (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2
- RNF31 | chr14:24146955 C>T | 5'Flank (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- ROPN1L | c.593+104C>T | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs1423003328; called by muse, mutect2
- RPS6 | c.6+91T>G | Intron (SNP) | VAF 129/429 reads (30%) | called by muse, mutect2, varscan2
- SDC1 | c.*35C>T | 3'UTR (SNP) | VAF 52/103 reads (50%) | catalogued as rs762047265; called by muse, mutect2, varscan2
- SEC24A | c.*514C>G | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, varscan2
- SFXN5 | c.357+108C>G | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- SGIP1 | c.*377G>C | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- SLC49A4 | c.*1625C>G | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- SLC6A10P | n.3786C>T | RNA (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- SMYD2 | c.*94C>T | 3'UTR (SNP) | VAF 48/79 reads (61%) | called by muse, mutect2, varscan2
- SNORD115-32 | n.12G>A | RNA (SNP) | VAF 18/42 reads (43%) | catalogued as rs769884390; called by muse, mutect2, varscan2
- SOCS4 | c.*3295G>C | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- STAT1 | c.2135+382A>G | Intron (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- STAT6 | c.1955+49T>A | Intron (SNP) | VAF 83/204 reads (41%) | called by muse, mutect2
- TAFA5 | c.*2030C>T | 3'UTR (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- TMEM138 | c.376+111G>C | Intron (SNP) | VAF 51/96 reads (53%) | called by muse, varscan2
- TNFRSF11B | c.401-1716G>A | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- TNPO2 | c.-13-368_-13-346del | Intron (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- TTC12 | c.445-86C>T | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- UBA52 | c.293+42G>A | Intron (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- UBA52 | c.*16G>A | 3'UTR (SNP) | VAF 21/55 reads (38%) | catalogued as rs1393859181; called by muse, mutect2
- UQCRC1 | chr3:48609779 G>A | 5'Flank (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- UTS2B | c.-664-330G>A | Intron (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- WFDC3 | chr20:45791929 C>T | 5'Flank (SNP) | VAF 9/42 reads (21%) | catalogued as rs1490768681; called by muse, mutect2, varscan2
- WWTR1 | c.*2372C>T | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- Z82195.2 | n.416-19529C>T | Intron (SNP) | VAF 50/107 reads (47%) | catalogued as rs1422810848; called by muse, mutect2, varscan2
- ZC3H11B | chr1:219609590 T>G | 3'Flank (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2, varscan2
- ZNF248 | c.*2062C>G | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- ZNF552 | chr19:57819737 G>A | 5'Flank (SNP) | VAF 60/161 reads (37%) | called by muse, mutect2, varscan2
- ZNF580 | c.-12-13C>T | Intron (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- ZNF791 | c.*2248G>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- ZXDA | c.-3G>A | 5'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
